Somatic mutation profile of tumor specimen ALCH-AEJR-TTP1-A (aliquot ALCH-AEJR-TTP1-A-2-0-D-A605-36) from ALCHEMIST case ALCH-AEJR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma with mixed subtypes; Age at diagnosis: 52.7 years (19,244 days).
Specimen ALCH-AEJR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 019d7642-d7ff-4836-95f8-6fb1789d4bf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJR-NB1-A (Blood Derived Normal), aliquot ALCH-AEJR-NB1-A-2-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ce71842-a85a-41b2-bb2e-70400e4c4ac7

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, RNA 2, 5'UTR 1, IGR 1, In Frame Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2308_2316dup p.D770_P772dup | In Frame Ins (INS) | VAF 182/526 reads (35%) | hotspot (GDC flag); catalogued as COSV51782050, COSV51798189; called by mutect2, varscan2
- ALMS1 | c.6085A>G p.T2029A | Missense Mutation (SNP) | VAF 76/504 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs759478895; called by muse, mutect2, varscan2
- BCR | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs765337010; called by muse, mutect2
- CCDC33 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1244599056; called by muse, mutect2
- PCDHA1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 40/644 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.413); catalogued as rs1554117874, COSV65376238; called by muse, mutect2
- REXO4 | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1196429362; called by muse, mutect2, varscan2
- SEMA5A | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1407782671, COSV66789974; called by muse, mutect2
- ZNF75D | c.697-1G>C p.X233_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | catalogued as rs369581520; called by muse, mutect2
- ADAMTSL1 | c.392T>G p.V131G | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- CAPZA2 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- DACH2 | c.1445A>C p.Q482P | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); called by muse, mutect2
- ECT2 | c.718C>A p.P240T (on ENST00000392692 / NM_001349098.2; = p.P209T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FSTL5 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 40/412 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.053); called by muse, mutect2
- HOXC13 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2
- IFT172 | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTM | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUDCD1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 133/439 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH12 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- PHF20 | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POF1B | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); called by muse, mutect2
- PPP6R3 | c.1374G>T p.M458I (on ENST00000393800 / NM_001352375.2; = p.M407I on NM_018312.5) | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- TAF5 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPBGL | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- VILL | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- VWDE | c.2563G>T p.V855L | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR3 | c.2922C>T p.A974= | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- GP6 | c.780T>G p.P260= | Silent (SNP) | VAF 26/896 reads (3%) | called by muse, mutect2
- GREB1 | c.4431C>A p.G1477= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, varscan2
- LAMP2 | c.291C>A p.S97= | Silent (SNP) | VAF 41/453 reads (9%) | called by muse, mutect2
- MYBPC3 | c.2511C>A p.I837= | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2, varscan2
- OR51G1 | c.858A>T p.P286= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- OR6N1 | c.288G>T p.G96= | Silent (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2, varscan2
- RBM18 | c.498T>G p.V166= | Silent (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- RHOB | c.169C>T p.L57= | Silent (SNP) | VAF 28/296 reads (9%) | catalogued as rs771157145; called by muse, mutect2
- SLC8A2 | c.2583C>T p.L861= | Silent (SNP) | VAF 15/297 reads (5%) | catalogued as rs1256327029; called by muse, mutect2
- SPG7 | c.1788C>T p.A596= (on ENST00000268704; = p.A603= on NM_003119.4) | Silent (SNP) | VAF 67/943 reads (7%) | catalogued as COSV51950345; called by muse, mutect2
- L3MBTL1 | c.2394+53C>T | Intron (SNP) | VAF 52/515 reads (10%) | catalogued as rs775537073, COSV64228136; called by muse, mutect2
- LINC01164 | n.963C>T | RNA (SNP) | VAF 30/435 reads (7%) | called by muse, mutect2
- MXRA8 | c.-1C>T | 5'UTR (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- SNORD116-10 | n.97A>G | RNA (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- Unknown | chr2:111238316 G>A | IGR (SNP) | VAF 20/119 reads (17%) | catalogued as rs1250426632; called by muse, mutect2, varscan2
